Somatic mutation profile of tumor specimen TCGA-97-7554-01A (aliquot TCGA-97-7554-01A-11D-2036-08) from TCGA case TCGA-97-7554, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 83.0 years (30,327 days).
Specimen TCGA-97-7554-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90ea3402-5438-48d7-8195-7207a5b4ab98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-7554-10A (Blood Derived Normal), aliquot TCGA-97-7554-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df6156a5-6f74-4dce-8f2e-8f98550c6b6c

The open-access MAF lists 468 somatic variants for this specimen: 352 protein-altering or splice-affecting, 105 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 309, Silent 105, Nonsense Mutation 18, Frame Shift Del 9, Splice Site 8, Frame Shift Ins 5, 3'UTR 3, RNA 3, Intron 2, 5'Flank 2, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs118192160, CM061939, CM140861, COSV62087706, COSV62099686; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 24/52 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2M | c.3272T>C p.I1091T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs773333847, COSV59387953; called by muse, mutect2, varscan2
- AADAC | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51759894; called by muse, mutect2, varscan2
- ABCA7 | c.4206-1G>T p.X1402_splice | Splice Site (SNP) | VAF 51/86 reads (59%) | catalogued as COSV54031184; called by muse, mutect2, varscan2
- ABCB1 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55953276; called by muse, mutect2, varscan2
- ABCC8 | c.3712C>T p.L1238F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV56851752; called by muse, mutect2
- ACTN2 | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV63975613; called by muse, mutect2, varscan2
- ACVR1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV55119533; called by muse, mutect2, varscan2
- ADAD1 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV56644076; called by muse, mutect2, varscan2
- ADAMTS15 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs1443294752, COSV54506294; called by muse, mutect2, varscan2
- ADAMTSL2 | c.540C>A p.C180* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV63203188, COSV63204677; called by muse, mutect2, varscan2
- ADCY1 | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV52035852; called by muse, mutect2, varscan2
- ADGRE5 | c.1537T>C p.C513R (on ENST00000242786 / NM_078481.4; = p.C420R on NM_001784.5) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54391998; called by muse, mutect2, varscan2
- AKR1C4 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs781870024, COSV54123617; called by muse, mutect2
- ALDH4A1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV51893435; called by muse, mutect2, varscan2
- ALPK2 | c.3430C>A p.Q1144K | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV64493762; called by muse, mutect2
- ANK1 | c.3287del p.P1096Rfs*9 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV55883723; called by mutect2, pindel, varscan2
- ANK2 | c.8718G>T p.M2906I | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV52165644; called by muse, mutect2, varscan2
- ANKK1 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58271572, COSV58272294; called by muse, mutect2
- ANKRD30A | c.3098A>T p.Q1033L (on ENST00000611781; = p.Q977L on NM_052997.2) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as COSV64612278; called by muse, mutect2, varscan2
- ANO3 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.051); catalogued as COSV56794112, COSV56795513; called by muse, mutect2, varscan2
- APBB3 | c.723T>A p.S241R (on ENST00000357560 / NM_133173.2; = p.S248R on NM_006051.3) | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV60052793; called by muse, mutect2, varscan2
- ARHGAP36 | c.620A>T p.Q207L | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV52267738; called by muse, mutect2, varscan2
- AUTS2 | c.3177G>T p.E1059D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as COSV61407673; called by muse, mutect2, varscan2
- BCL11A | c.955C>A p.P319T (on ENST00000335712 / NM_001365609.1; = p.P353T on NM_018014.4) | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59629449, COSV59631290; called by muse, mutect2, varscan2
- BCORL1 | c.2833C>T p.R945* | Nonsense Mutation (SNP) | VAF 17/150 reads (11%) | catalogued as COSV54390955, COSV54395969; called by muse, mutect2, varscan2
- BDP1 | c.4426A>G p.M1476V | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1027727364, COSV62431932; called by muse, mutect2
- BEND2 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as COSV66216107; called by muse, mutect2, varscan2
- BEND6 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66069169; called by muse, mutect2, varscan2
- BRCA1 | c.4265G>T p.G1422V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100524688; called by muse, mutect2, varscan2
- BRCA2 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.228); catalogued as COSV66455084, COSV66461336; called by muse, mutect2, varscan2
- BRSK2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs1204118010, COSV57544062; called by muse, mutect2
- BTBD17 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV100945204, COSV64730023; called by muse, mutect2, varscan2
- C4orf17 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV58512684; called by muse, mutect2, varscan2
- CACNA1E | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62399525; called by muse, mutect2
- CACNG2 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV55635828; called by muse, varscan2
- CARD11 | c.1298G>C p.S433T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV67799738; called by muse, mutect2, varscan2
- CBFA2T3 | c.1529C>G p.S510W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV51927904, COSV99241825; called by muse, mutect2, varscan2
- CBX2 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53969312; called by muse, mutect2, varscan2
- CDH17 | c.178T>G p.F60V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV50330197; called by muse, mutect2, varscan2
- CDH20 | c.1821C>A p.S607R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV53011226; called by muse, mutect2, varscan2
- CDH23 | c.7048T>A p.S2350T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV56469330; called by muse, mutect2, varscan2
- CDH9 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV50299187, COSV50315398, COSV99161153; called by muse, mutect2, varscan2
- CEP104 | c.2464G>T p.E822* | Nonsense Mutation (SNP) | VAF 33/132 reads (25%) | catalogued as COSV65517853; called by muse, mutect2, varscan2
- CEP126 | c.1676A>G p.H559R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV54826194; called by muse, mutect2, varscan2
- CHRM4 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV58989733, COSV58995332; called by muse, mutect2, varscan2
- CHRNB3 | c.468C>G p.D156E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV51494874, COSV51495474; called by muse, mutect2, varscan2
- CHRNG | c.351C>A p.N117K | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV67315638; called by muse, mutect2, varscan2
- CLVS2 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.701); catalogued as COSV51563903; called by muse, mutect2, varscan2
- CNKSR2 | c.66T>C p.G22= | Splice Region (SNP) | VAF 4/50 reads (8%) | catalogued as COSV54257940; called by muse, mutect2
- CNOT1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57772128; called by muse, mutect2, varscan2
- CNR1 | c.1048G>C p.V350L | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs1224759048, COSV62987821; called by muse, mutect2
- COL15A1 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV66645911; called by muse, mutect2
- COL5A1 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65669942; called by muse, mutect2, varscan2
- CPA6 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV52731732; called by muse, mutect2, varscan2
- CPED1 | c.2248C>A p.H750N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV60004145; called by muse, mutect2, varscan2
- CPSF2 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV54098740; called by muse, mutect2, varscan2
- CRIP3 | c.197-1G>T p.X66_splice | Splice Site (SNP) | VAF 21/90 reads (23%) | catalogued as COSV51484275; called by muse, mutect2, varscan2
- CSMD1 | c.1141G>T p.V381L (on ENST00000520002; = p.V380L on NM_033225.6) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.9); catalogued as COSV68213087; called by muse, mutect2
- CSMD3 | c.10468G>T p.V3490F (on ENST00000297405 / NM_001363185.1; = p.V3321F on NM_052900.3) | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52202468; called by muse, mutect2, varscan2
- CST3 | c.359A>T p.K120I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV65362045; called by muse, mutect2, varscan2
- CTCFL | c.835del p.H279Tfs*13 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as COSV54770288; called by mutect2, pindel, varscan2
- CTR9 | c.2165A>G p.Y722C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs1376432143, COSV63728826; called by muse, mutect2, varscan2
- CUEDC1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV64226560; called by muse, mutect2, varscan2
- CYP11B2 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751082074, COSV59996301; called by muse, mutect2, varscan2
- DCDC1 | c.920A>T p.D307V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV60844797; called by muse, mutect2, varscan2
- DCSTAMP | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV52578112; called by muse, mutect2, varscan2
- DIP2A | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59479058; called by muse, mutect2, varscan2
- DNAH11 | c.8375G>C p.R2792T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV60959790; called by muse, mutect2
- DNAH5 | c.9947del p.P3316Lfs*22 | Frame Shift Del (DEL) | VAF 67/211 reads (32%) | catalogued as rs1206989225; called by mutect2, pindel, varscan2
- DNAI3 | c.242G>T p.R81I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54003192; called by muse, mutect2, varscan2
- DSC2 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1617629; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYDC1 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.023); catalogued as COSV55472574; called by muse, mutect2, varscan2
- DYNC1I1 | c.1915G>T p.G639C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV61462411; called by muse, mutect2, varscan2
- DYNC2H1 | c.11579G>T p.R3860L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV62090901, COSV62096087, COSV62100246; called by muse, mutect2, varscan2
- DYSF | c.4717C>T p.Q1573* | Nonsense Mutation (SNP) | VAF 32/161 reads (20%) | catalogued as COSV50447631; called by muse, mutect2, varscan2
- EDIL3 | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV56901637; called by muse, mutect2, varscan2
- EMC1 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313822295, COSV64345895; called by muse, mutect2
- ERMN | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV68075418; called by muse, mutect2, varscan2
- ERN2 | c.2216C>A p.P739H | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99891898; called by muse, mutect2, varscan2
- ERN2 | c.2215C>A p.P739T | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV55623354; called by muse, mutect2, varscan2
- ESR1 | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV52797407, COSV99240095; called by muse, mutect2, varscan2
- EZH2 | c.1021G>A p.E341K (on ENST00000460911 / NM_001203247.2; = p.E346K on NM_004456.5) | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as COSV57454778; called by muse, mutect2
- F13B | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66374226; called by muse, mutect2, varscan2
- FA2H | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as rs752782914, COSV54726539; called by muse, mutect2, varscan2
- FAM118A | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53417651; called by muse, mutect2, varscan2
- FAM47C | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.475); catalogued as COSV63723585; called by muse, mutect2, varscan2
- FAR2 | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV51726317; called by muse, mutect2, varscan2
- FBXL7 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV61647265; called by muse, mutect2, varscan2
- FBXO15 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV54046093; called by muse, mutect2, varscan2
- FBXO28 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV64800605; called by muse, mutect2, varscan2
- FBXO40 | c.994A>G p.R332G | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV57524641; called by muse, mutect2, varscan2
- FGA | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV57396973; called by muse, mutect2, varscan2
- FGD5 | c.1165A>T p.M389L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs753113394, COSV53244565; called by muse, mutect2, varscan2
- FGF16 | c.601A>G p.R201G | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); catalogued as COSV71546213; called by muse, mutect2, varscan2
- FLT1 | c.3706A>T p.T1236S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV56729989; called by muse, mutect2, varscan2
- FREM1 | c.6460G>T p.V2154F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV66524914; called by muse, mutect2, varscan2
- FRMD6 | c.1366G>A p.E456K (on ENST00000344768 / NM_001267046.2; = p.E448K on NM_152330.4) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs1179135910, COSV61088815; called by muse, mutect2, varscan2
- FRMPD1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63383415; called by muse, mutect2, varscan2
- GABRA2 | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62915727; called by muse, mutect2
- GABRG3 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61520398; called by muse, mutect2, varscan2
- GARRE1 | c.849A>T p.A283= | Splice Region (SNP) | VAF 16/51 reads (31%) | catalogued as COSV55100041; called by muse, mutect2, varscan2
- GATM | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.744); catalogued as COSV67540598; called by muse, mutect2, varscan2
- GGA3 | c.283A>C p.K95Q | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55457104; called by muse, mutect2, varscan2
- GJB4 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV58356362, COSV58356602; called by muse, mutect2, varscan2
- GLMN | c.1019A>T p.E340V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as COSV64860564; called by muse, mutect2, varscan2
- GLRA3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs1395553136, COSV56863234; called by muse, mutect2, varscan2
- GPR65 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.23); catalogued as COSV50862941; called by muse, mutect2, varscan2
- GPRC5B | c.1014G>T p.M338I | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV56026956; called by muse, mutect2, varscan2
- GRID1 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV60032798, COSV60047466; called by muse, mutect2, varscan2
- GRIK1 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV58720521; called by muse, mutect2, varscan2
- GRM2 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56585388; called by muse, mutect2, varscan2
- GTPBP10 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55986670, COSV55987962; called by muse, mutect2, varscan2
- HDC | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51071553; called by muse, mutect2, varscan2
- HECW1 | c.764T>A p.I255N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV67831359; called by muse, mutect2, varscan2
- HECW1 | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.36); catalogued as COSV101223036, COSV67831366; called by muse, mutect2, varscan2
- HERC1 | c.4927C>T p.Q1643* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV71248169; called by muse, mutect2
- HIVEP2 | c.4010G>A p.R1337Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752865742, COSV50014012; called by muse, mutect2, varscan2
- HPSE2 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV65190988; called by muse, mutect2, varscan2
- HTR1F | c.519C>G p.I173M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.902); catalogued as COSV60389937; called by muse, mutect2, varscan2
- IGLON5 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54536211, COSV54536292; called by muse, mutect2, varscan2
- IMPDH1 | c.1454G>A p.G485E (on ENST00000470772 / NM_001142573.2; = p.G571E on NM_000883.4) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100118666, COSV58316420; called by muse, mutect2
- INKA1 | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as COSV58525872, COSV58526311; called by muse, mutect2, varscan2
- INSC | c.1639T>C p.C547R | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV65411097; called by muse, mutect2, varscan2
- INSRR | c.3385G>T p.V1129F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63872420, COSV63874333; called by muse, mutect2, varscan2
- IRS4 | c.2201G>T p.R734L | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV100929673, COSV64534198; called by muse, mutect2, varscan2
- IRX4 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as COSV51473136, COSV99180759; called by muse, mutect2, varscan2
- ITIH3 | c.2032C>A p.R678S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV69649186, COSV69650925; called by muse, mutect2, varscan2
- JAK3 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV71686146; called by muse, mutect2, varscan2
- KCNA4 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60252888; called by muse, mutect2, varscan2
- KCNK16 | c.830C>A p.A277E | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64678354, COSV64678432; called by muse, mutect2, varscan2
- KIAA1210 | c.3542G>T p.G1181V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.813); catalogued as COSV68177560; called by muse, mutect2, varscan2
- KIF4B | c.1466A>G p.D489G | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs768487824, COSV70529872; called by muse, mutect2, varscan2
- KIF4B | c.3117G>C p.M1039I | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV70529880; called by muse, mutect2, varscan2
- KLHL36 | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV50719696; called by muse, mutect2
- KRT36 | c.270C>A p.N90K | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV60203621; called by muse, mutect2, varscan2
- KRT37 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217169533, COSV56658407; called by muse, mutect2, varscan2
- KRTAP10-9 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV59965912; called by muse, mutect2, varscan2
- KRTAP19-7 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 156/251 reads (62%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV58366225; called by muse, mutect2, varscan2
- KRTAP6-2 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 111/171 reads (65%) | PolyPhen possibly damaging (0.535); catalogued as COSV58182137, COSV58182417; called by muse, mutect2, varscan2
- LAMA3 | c.8690G>A p.S2897N (on ENST00000313654 / NM_198129.4; = p.S1288N on NM_000227.6) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV52535924; called by muse, mutect2, varscan2
- LCE2D | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV100909528, COSV64229271; called by muse, mutect2, varscan2
- LDHA | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV57040560; called by muse, mutect2, varscan2
- LILRA1 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52181476; called by muse, mutect2, varscan2
- LRP1B | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV67230234; called by muse, mutect2
- LRP1B | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV67216959, COSV67230240; called by muse, mutect2, varscan2
- LRRC14B | c.1356C>A p.D452E | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57257096; called by muse, mutect2, varscan2
- LRRC7 | c.3258A>G p.I1086M (on ENST00000651989 / NM_001370785.2; = p.I1053M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.12); catalogued as COSV50473804; called by muse, mutect2, varscan2
- LUM | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV57128389; called by muse, mutect2, varscan2
- LY75 | c.4225A>G p.I1409V | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV55107191; called by muse, mutect2, varscan2
- MAGEA6 | c.891del p.R298Afs*12 | Frame Shift Del (DEL) | VAF 38/346 reads (11%) | catalogued as COSV61449358; called by mutect2, varscan2
- MAGEB4 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100974916, COSV66775861; called by muse, mutect2, varscan2
- MAGEB6 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV66871931, COSV66872393; called by muse, mutect2, varscan2
- MAGEC2 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 189/314 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV55999665; called by muse, mutect2, varscan2
- MAGEE1 | c.1195G>C p.G399R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV63910578; called by muse, mutect2, varscan2
- MAMDC4 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56033226; called by muse, mutect2, varscan2
- MAMLD1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV53375923; called by muse, mutect2
- MASP1 | c.1623C>A p.H541Q | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1234434548, COSV61827367; called by muse, mutect2, varscan2
- MECOM | c.227T>G p.I76S | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV72109724, COSV72110524; called by muse, mutect2, varscan2
- MEGF6 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs201247174, COSV53890906; called by muse, mutect2, varscan2
- MFNG | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.073); catalogued as COSV52657406; called by muse, mutect2, varscan2
- MOCOS | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV54344430; called by muse, mutect2, varscan2
- MORN1 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV66003099; called by muse, mutect2, varscan2
- MPPE1 | c.962T>G p.V321G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52328326; called by muse, varscan2
- MRGPRX3 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283567; called by muse, varscan2
- MRGPRX3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101283566, COSV101283568; called by muse, mutect2, varscan2
- MROH2B | c.3571C>T p.Q1191* | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | catalogued as COSV68185091; called by muse, mutect2, varscan2
- MTG1 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV53372879; called by muse, mutect2, varscan2
- MTMR11 | c.272C>G p.P91R (on ENST00000439741 / NM_001145862.2; = p.P19R on NM_181873.3) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.564); catalogued as COSV63806688; called by muse, mutect2, varscan2
- MTOR | c.6752G>A p.R2251Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63872621; called by muse, mutect2
- MUC6 | c.2945G>A p.R982K | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV70142994; called by muse, mutect2, varscan2
- MYADM | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV61238510, COSV61239936; called by muse, mutect2, varscan2
- MYO9B | c.4732A>G p.T1578A | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV68279812; called by muse, mutect2
- MYOF | c.3140A>G p.D1047G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63705324; called by muse, mutect2, varscan2
- MYOM2 | c.2374G>T p.G792C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34863717, COSV50720369; called by muse, mutect2, varscan2
- NAGK | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as COSV54903776; called by muse, mutect2, varscan2
- NCF2 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV62315730; called by muse, mutect2, varscan2
- NCKAP5 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV58448773; called by mutect2, varscan2
- NDUFB11 | c.284T>A p.V95D | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV52102345; called by muse, mutect2, varscan2
- NDUFS4 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as COSV57019448; called by muse, mutect2, varscan2
- NECTIN1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.875); catalogued as COSV50599872; called by muse, mutect2, varscan2
- NFASC | c.3325_3326insA p.G1109Efs*44 (on ENST00000339876 / NM_001378329.1; = p.G1038Efs*44 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/133 reads (12%) | catalogued as COSV100364811; called by mutect2, pindel, varscan2
- NFASC | c.3689C>T p.T1230M (on ENST00000339876 / NM_001378329.1; = p.T1159M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs376304938; called by muse, mutect2, varscan2
- NID2 | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs778840585, COSV53497530; called by muse, mutect2, varscan2
- NKD2 | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56892275; called by muse, mutect2, varscan2
- NLRP12 | c.2250G>T p.K750N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.959); catalogued as COSV60748882; called by muse, mutect2, varscan2
- NLRP5 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1471811474, COSV66765221, COSV66766883; called by muse, mutect2
- NLRP7 | c.2443C>T p.R815C (on ENST00000340844 / NM_206828.3; = p.R787C on NM_139176.3) | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs768718588, COSV60175308; called by muse, mutect2, varscan2
- NLRP7 | c.618C>A p.Y206* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV100051385, COSV60175821; called by muse, mutect2, varscan2
- NOTCH4 | c.2668G>T p.A890S | Missense Mutation (SNP) | VAF 113/192 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66681291; called by muse, mutect2, varscan2
- NPY2R | c.737T>A p.L246* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as rs1255320290, COSV61528523; called by muse, mutect2, varscan2
- NRG3 | c.1315G>C p.A439P | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as COSV64566614; called by muse, mutect2, varscan2
- NSD2 | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV56391831; called by muse, mutect2, varscan2
- NTRK2 | c.2058G>C p.E686D (on ENST00000323115 / NM_001369534.1; = p.E702D on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as COSV52866561, COSV52882758; called by muse, mutect2, varscan2
- OPLAH | c.2718G>T p.K906N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV70678219; called by muse, mutect2, varscan2
- OR10A4 | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as COSV65842098; called by muse, mutect2, varscan2
- OR10AG1 | c.869T>A p.V290E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV56633272; called by muse, mutect2, varscan2
- OR14C36 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.335); catalogued as COSV58601578; called by muse, mutect2, varscan2
- OR14I1 | c.860T>A p.I287K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61199797; called by muse, mutect2, varscan2
- OR14J1 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 106/214 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV65845729; called by muse, mutect2, varscan2
- OR2M5 | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63546418; called by muse, mutect2, varscan2
- OR4C15 | c.1002G>T p.L334F (on ENST00000314644; = p.L280F on NM_001001920.2) | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.222); catalogued as COSV100115651, COSV58953273; called by muse, mutect2, varscan2
- OR4C46 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.065); catalogued as COSV60219791, COSV60219815; called by muse, mutect2, varscan2
- OR51A4 | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100985171, COSV100985302; called by muse, varscan2
- OR51A4 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs375550618, COSV100985252; called by muse, varscan2
- OR52N4 | c.445G>C p.A149P | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV57891395; called by muse, mutect2, varscan2
- OR56A3 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61569164, COSV61569281; called by muse, mutect2, varscan2
- OR5D14 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs200877014, COSV59455703; called by muse, mutect2, varscan2
- OR5J2 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1452063447, COSV56621823; called by muse, mutect2, varscan2
- OR6Q1 | c.11A>T p.Y4F | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.029); catalogued as COSV56933375; called by muse, mutect2, varscan2
- OR8G1 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100422547; called by muse, mutect2, varscan2
- OTUD4 | c.3219G>T p.W1073C (on ENST00000447906 / NM_001366057.1; = p.W1008C on NM_001102653.1) | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs193048642; called by muse, mutect2, varscan2
- PACC1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.418); catalogued as rs778308357, COSV54788298; called by muse, mutect2
- PAPPA | c.3728G>T p.R1243L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60285039, COSV60290277; called by muse, mutect2, varscan2
- PCDH10 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as COSV52096060, COSV52100038; called by muse, mutect2, varscan2
- PCDH10 | c.1443C>A p.Y481* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV52096066; called by muse, mutect2, varscan2
- PCDH11X | c.3809G>C p.S1270T | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53473053; called by muse, mutect2, varscan2
- PCDHA13 | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 83/149 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV56509962, COSV56525696; called by muse, mutect2, varscan2
- PCDHA7 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.154); catalogued as COSV100971643; called by muse, mutect2, varscan2
- PCDHGA9 | c.1990A>T p.I664L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV53963733; called by muse, mutect2, varscan2
- PCF11 | c.99C>A p.S33R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53532257; called by muse, mutect2, varscan2
- PEX2 | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV63813685; called by muse, mutect2
- PGK2 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59164163; called by muse, mutect2, varscan2
- PHLDB3 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV52669465; called by muse, mutect2, varscan2
- PLA2R1 | c.2382G>T p.W794C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51780190; called by muse, mutect2, varscan2
- PLB1 | c.56-2A>T p.X19_splice | Splice Site (SNP) | VAF 28/110 reads (25%) | catalogued as COSV59827495; called by muse, mutect2, varscan2
- PLPPR4 | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64566199; called by muse, mutect2, varscan2
- POSTN | c.219-2A>T p.X73_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV65713272; called by muse, mutect2, varscan2
- POU6F2 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68874600; called by muse, mutect2, varscan2
- PPP2R2B | c.1061T>G p.M354R (on ENST00000394409; = p.M420R on NM_181674.2) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV60766544; called by muse, mutect2, varscan2
- PPP6R1 | c.1506G>T p.W502C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69799907; called by muse, mutect2, varscan2
- PRAME | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV67161746; called by muse, mutect2, varscan2
- PRDM14 | c.530A>T p.Q177L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52572883; called by muse, mutect2, varscan2
- PRDM2 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV52448590; called by muse, varscan2
- PRDM9 | c.2198C>A p.S733* | Nonsense Mutation (SNP) | VAF 43/256 reads (17%) | catalogued as COSV57007498; called by muse, varscan2
- PREPL | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53217139; called by muse, mutect2, varscan2
- PRKCQ | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.317); catalogued as rs780846102, COSV54112580; called by muse, mutect2, varscan2
- PRKG2 | c.1894G>T p.D632Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779096403, COSV52325351; called by muse, mutect2, varscan2
- PROS1 | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62398701; called by muse, mutect2, varscan2
- PRPF40B | c.1229G>T p.R410L (on ENST00000380281; = p.R404L on NM_012272.3) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56058240, COSV56059786; called by muse, mutect2, varscan2
- PRRC2A | c.3910G>T p.A1304S | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.846); catalogued as COSV65687138; called by muse, mutect2, varscan2
- PRSS22 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50721984; called by muse, mutect2, varscan2
- PRSS58 | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.076); catalogued as COSV73488698; called by muse, mutect2, varscan2
- PTGR1 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53029055; called by muse, mutect2, varscan2
- PTPN23 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV55545323; called by muse, mutect2, varscan2
- PTPRT | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61987161, COSV62025972; called by muse, mutect2, varscan2
- PTPRZ1 | c.2831A>G p.Y944C | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as COSV66438215; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV57929792; called by muse, mutect2, varscan2
- RAD54L | c.605G>C p.R202P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64336249; called by muse, mutect2, varscan2
- RADX | c.1634G>T p.R545M | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65319013; called by muse, mutect2, varscan2
- RASA3 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV61868285; called by muse, mutect2, varscan2
- REG1A | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52069986; called by muse, mutect2, varscan2
- REG1B | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59304610; called by muse, mutect2, varscan2
- REG3A | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as COSV59409866; called by muse, mutect2, varscan2
- RELN | c.5035T>A p.S1679T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV59007540; called by muse, mutect2, varscan2
- RGS12 | c.4214G>T p.G1405V (on ENST00000336727; = p.G757V on NM_198227.2) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.619); catalogued as COSV58753009; called by muse, mutect2, varscan2
- RIMS1 | c.4561G>T p.D1521Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53460023; called by muse, mutect2, varscan2
- RIOK3 | c.1255G>T p.V419F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59773370; called by muse, mutect2, varscan2
- RIOX2 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57724285; called by muse, mutect2, varscan2
- RIT2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1162004248, COSV56301378; called by muse, mutect2, varscan2
- RNF113A | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV65097445; called by muse, mutect2, varscan2
- RNF216 | c.1376A>T p.K459M (on ENST00000425013 / NM_207116.3; = p.K516M on NM_207111.4) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs757713293, COSV66290864; called by muse, mutect2, varscan2
- RPAP1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV100427222; called by muse, mutect2
- RPAP1 | c.1292C>G p.A431G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV58539841; called by muse, mutect2
- RPAP1 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV58539851; called by muse, varscan2
- RPAP1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV58539858; called by muse, varscan2
- RPTOR | c.3418A>T p.S1140C | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60809946; called by muse, mutect2, varscan2
- RXYLT1 | c.541T>A p.L181I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99707026; called by muse, mutect2, varscan2
- RYR2 | c.7517C>T p.A2506V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.576); catalogued as COSV63689868; called by muse, mutect2, varscan2
- RYR2 | c.12301C>A p.L4101I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63686373, COSV63689874; called by muse, mutect2, varscan2
- SART1 | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV56712044; called by muse, mutect2, varscan2
- SDK2 | c.6312G>T p.E2104D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.08); catalogued as COSV66187681; called by muse, mutect2, varscan2
- SETBP1 | c.1063G>T p.V355F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as rs752918225, COSV56321926, COSV56324820; called by muse, mutect2, varscan2
- SH2D1A | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.534); catalogued as COSV63579185, COSV63579843; called by muse, mutect2, varscan2
- SH3PXD2B | c.941A>T p.K314M | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV61127439; called by muse, mutect2, varscan2
- SIGLEC14 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as COSV99707284; called by muse, mutect2
- SLAMF1 | c.66C>G p.S22R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52499679; called by muse, mutect2, varscan2
- SLAMF9 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs775061961, COSV63636781; called by muse, mutect2, varscan2
- SLC10A3 | c.840C>A p.D280E | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54836534, COSV54836737; called by muse, mutect2, varscan2
- SLC12A4 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57930693; called by muse, mutect2, varscan2
- SLC23A2 | c.1548C>A p.N516K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57775287; called by muse, mutect2, varscan2
- SLC34A1 | c.1333C>A p.L445M | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60997128; called by muse, mutect2, varscan2
- SLC6A1 | c.769C>A p.R257S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV55115908; called by muse, mutect2, varscan2
- SLC7A9 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV50086537; called by muse, mutect2
- SLCO1B1 | c.1363C>A p.P455T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV57012150; called by muse, mutect2, varscan2
- SP100 | c.293A>T p.N98I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50982123; called by muse, mutect2, varscan2
- SRBD1 | c.2929G>T p.V977L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55399686; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | PolyPhen benign (0.009); catalogued as COSV59566518; called by muse, mutect2, varscan2
- STAG3 | c.3443G>T p.R1148M | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as COSV57931238; called by muse, mutect2, varscan2
- SULT1A2 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1285784324, COSV57682013; called by muse, mutect2, varscan2
- TAP1 | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.618); catalogued as COSV62754749; called by muse, mutect2, varscan2
- TAS1R2 | c.1015C>A p.R339S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV100946288; called by muse, mutect2, varscan2
- TDP2 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV61967508; called by muse, mutect2, varscan2
- TDRD10 | c.953-1G>C p.X318_splice | Splice Site (SNP) | VAF 11/97 reads (11%) | catalogued as COSV52725398; called by muse, mutect2, varscan2
- TENM3 | c.5629C>T p.R1877W | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771356366, COSV69310319; called by muse, mutect2, varscan2
- TEX13B | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV57203106; called by muse, mutect2
- THBS2 | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV64679476; called by muse, mutect2, varscan2
- TMCC3 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as COSV54154979; called by muse, mutect2, varscan2
- TMEM131L | c.2750A>T p.N917I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV53645472; called by muse, mutect2, varscan2
- TMEM187 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs372840875, COSV64141713; called by muse, mutect2
- TMIGD2 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV56667311; called by muse, varscan2
- TP53I11 | c.526A>T p.I176F | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV57533359; called by muse, mutect2, varscan2
- TPR | c.2001G>T p.E667D | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.525); catalogued as COSV66602031; called by muse, mutect2, varscan2
- TRPV5 | c.349+1G>T p.X117_splice | Splice Site (SNP) | VAF 39/129 reads (30%) | catalogued as rs1234897999, COSV54686734; called by muse, mutect2, varscan2
- TSHZ2 | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61589254; called by muse, mutect2, varscan2
- TSKU | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1486234266, COSV60751165; called by muse, mutect2, varscan2
- TTC29 | c.1022T>C p.V341A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs865854086, COSV57276586; called by muse, mutect2, varscan2
- TTC39C | c.1186G>T p.V396F (on ENST00000317571 / NM_001135993.2; = p.V335F on NM_153211.4) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58218009, COSV58220277; called by muse, mutect2
- TTLL3 | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs773767198, COSV59614660; called by muse, mutect2, varscan2
- TTN | c.88862T>A p.V29621E (on ENST00000591111; = p.V22197E on NM_003319.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | PolyPhen benign (0.259); catalogued as COSV60113917; called by muse, mutect2, varscan2
- TTN | c.14902G>A p.A4968T (on ENST00000591111; = p.A4041T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/218 reads (4%) | PolyPhen benign (0); catalogued as COSV100615955, COSV60113963; called by muse, mutect2
- UBE2A | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100660503, COSV60636753; called by muse, mutect2, varscan2
- UGT8 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as COSV60418473, COSV60421580; called by muse, mutect2, varscan2
- UNC79 | c.3193G>T p.E1065* (on ENST00000393151 / NM_001346218.2; = p.E888* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV56379107, COSV56391667; called by muse, mutect2, varscan2
- USH2A | c.2669C>A p.T890N | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100232567, COSV100238644; called by muse, mutect2
- USP34 | c.1957A>G p.I653V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); catalogued as rs781723283, COSV68402060; called by mutect2, varscan2
- VANGL1 | c.529G>C p.A177P | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59620772; called by muse, mutect2, varscan2
- VSX1 | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV65021669, COSV65021775; called by muse, mutect2, varscan2
- WASF3 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs538866473, COSV58966978; called by muse, mutect2, varscan2
- WBP1L | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV64009878; called by muse, mutect2, varscan2
- WDR45 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100540328; called by mutect2, varscan2
- WDR64 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV63796716; called by muse, mutect2, varscan2
- YIPF3 | c.545C>A p.T182N | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV58305200; called by muse, mutect2, varscan2
- ZAN | c.3991C>G p.Q1331E | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100769986, COSV61810196; called by muse, mutect2
- ZHX1 | c.2042G>T p.R681L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV52876832, COSV52877718; called by muse, mutect2, varscan2
- ZIM2 | c.604A>T p.R202W | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV55636173; called by muse, mutect2, varscan2
- ZIM3 | c.597C>G p.S199R | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.102); catalogued as COSV54143514; called by muse, mutect2, varscan2
- ZNF28 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60423486; called by muse, mutect2, varscan2
- ZNF516 | c.2214G>T p.R738S | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV71587128; called by muse, mutect2, varscan2
- ZNF534 | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56518370; called by muse, mutect2, varscan2
- ZNF536 | c.3764C>A p.P1255H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV62821124, COSV62825853; called by muse, mutect2, varscan2
- ZNF560 | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs1474451498, COSV56866951; called by muse, mutect2
- ZNF610 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV58345119; called by mutect2, varscan2
- ZNF667 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs1363894135, COSV52635317; called by muse, mutect2
- ZNF98 | c.87C>A p.C29* | Nonsense Mutation (SNP) | VAF 49/125 reads (39%) | catalogued as rs758167798, COSV63337151; called by muse, mutect2, varscan2
- ZP4 | c.917C>G p.P306R | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63912270; called by muse, mutect2, varscan2
- ZW10 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV99562785; called by muse, mutect2, varscan2
- BTN3A1 | c.968del p.X323_splice | Splice Site (DEL) | VAF 15/147 reads (10%) | called by mutect2, pindel
- COL25A1 | c.672+1dup p.X224_splice | Splice Site (INS) | VAF 22/133 reads (17%) | called by mutect2, pindel, varscan2
- COL5A2 | c.3666dup p.P1223Sfs*19 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by pindel, varscan2
- CTNNA2 | c.101dup p.V35Gfs*15 | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | called by mutect2, pindel, varscan2
- FANCB | c.1198del p.V400Ffs*27 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- FLNC | c.1785A>T p.E595D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAB4 | c.408del p.R137Gfs*4 | Frame Shift Del (DEL) | VAF 49/268 reads (18%) | called by mutect2, pindel, varscan2
- HECW1 | c.10del p.H4Tfs*5 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- HNRNPUL1 | c.1088dup p.L363Ffs*44 | Frame Shift Ins (INS) | VAF 19/157 reads (12%) | called by mutect2, pindel, varscan2
- LTN1 | c.4358dup p.L1453Ffs*13 | Frame Shift Ins (INS) | VAF 54/118 reads (46%) | called by mutect2, pindel, varscan2
- NDRG2 | c.931del p.L311Cfs*12 (on ENST00000298687 / NM_001354570.1; = p.L297Cfs*12 on NM_016250.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/210 reads (12%) | called by mutect2, pindel, varscan2
- PCDHGA2 | c.755del p.P252Rfs*13 | Frame Shift Del (DEL) | VAF 36/103 reads (35%) | called by mutect2, pindel, varscan2
- TRBV27 | c.87C>A p.Y29* | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- AADACL4 | c.270C>A p.T90= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV66106449; called by muse, mutect2, varscan2
- ABCD2 | c.327G>T p.L109= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV58052275; called by muse, mutect2, varscan2
- ACO2 | c.99G>T p.A33= | Silent (SNP) | VAF 50/312 reads (16%) | catalogued as COSV53443234; called by muse, mutect2, varscan2
- ADGRB3 | c.4188A>T p.A1396= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV53247651; called by muse, mutect2, varscan2
- AFF1 | c.1839C>T p.A613= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV57119883, COSV57120549; called by muse, mutect2, varscan2
- AFF2 | c.2631C>A p.I877= | Silent (SNP) | VAF 168/370 reads (45%) | catalogued as COSV53992604; called by muse, varscan2
- AK1 | c.105C>T p.T35= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV56345286; called by muse, mutect2, varscan2
- ANKRD12 | c.1887T>C p.H629= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV50828086; called by muse, mutect2
- AP002512.3 | c.942C>A p.L314= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99688053; called by muse, mutect2, varscan2
- ASRGL1 | c.213A>G p.T71= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV57124983; called by muse, mutect2, varscan2
- BRCA1 | c.4266G>T p.G1422= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV100524687; called by muse, mutect2, varscan2
- CATSPER4 | c.69G>T p.G23= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV58793493; called by muse, mutect2, varscan2
- CDH15 | c.1404C>A p.T468= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV57024925; called by muse, mutect2, varscan2
- CDK15 | c.1212T>C p.F404= (on ENST00000652192 / NM_001366386.2; = p.F353= on NM_139158.2) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99643450; called by muse, mutect2, varscan2
- CHL1 | c.3615C>A p.P1205= (on ENST00000397491 / NM_001253387.1; = p.P1221= on NM_006614.4) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56595441, COSV99852545; called by muse, mutect2, varscan2
- CIT | c.5658G>A p.A1886= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as rs1373460666, COSV55871521; called by muse, mutect2, varscan2
- CNGB3 | c.666C>A p.L222= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV60691142; called by muse, mutect2, varscan2
- COL11A1 | c.2511T>A p.L837= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV62178127, COSV62185643; called by muse, mutect2, varscan2
- COL6A3 | c.5019C>A p.G1673= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV55092835; called by muse, mutect2, varscan2
- CUX2 | c.3813C>A p.T1271= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55635045; called by muse, mutect2, varscan2
- DCHS1 | c.574C>A p.R192= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV55036680; called by muse, mutect2, varscan2
- DIDO1 | c.4065G>T p.P1355= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as COSV56625003; called by muse, mutect2, varscan2
- DLG1 | c.726G>T p.T242= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV58384266; called by muse, mutect2, varscan2
- DLGAP5 | c.951G>A p.L317= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV55963590; called by muse, mutect2, varscan2
- DOCK2 | c.1290C>T p.L430= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as rs1196964571, COSV56962728; called by muse, mutect2
- DPEP3 | c.145C>T p.L49= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV52051598; called by muse, mutect2, varscan2
- DPP6 | c.405T>C p.D135= (on ENST00000377770 / NM_001364500.2; = p.D73= on NM_001936.5) | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs763429644, COSV59618975; called by muse, mutect2, varscan2
- DSCAM | c.3933G>T p.G1311= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as COSV68026163, COSV68028356; called by muse, mutect2
- F8 | c.3078A>G p.S1026= | Silent (SNP) | VAF 59/118 reads (50%) | catalogued as COSV64274454; called by muse, mutect2, varscan2
- FAT2 | c.1923A>C p.T641= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV55821233; called by muse, mutect2, varscan2
- FGF12 | c.495C>T p.R165= (on ENST00000454309 / NM_021032.5; = p.R103= on NM_004113.6) | Silent (SNP) | VAF 42/200 reads (21%) | catalogued as COSV53168847; called by muse, mutect2, varscan2
- FLNC | c.4536C>T p.P1512= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs753681622, COSV57957213; called by muse, mutect2, varscan2
- GPR141 | c.852C>T p.V284= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs751289202, COSV57731817; called by muse, mutect2, varscan2
- HCFC1 | c.6039C>A p.A2013= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as rs1557111900, COSV60073338; called by muse, mutect2
- HDAC9 | c.1269C>T p.P423= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV67775030; called by muse, mutect2, varscan2
- HOXA5 | c.300G>T p.P100= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1428198835, COSV56073558; called by muse, mutect2, varscan2
- ITGA4 | c.2916C>G p.P972= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV59208498; called by muse, mutect2, varscan2
- JADE3 | c.1884G>T p.S628= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs781813849, COSV54467144; called by muse, mutect2, varscan2
- KIF19 | c.1437G>A p.Q479= | Silent (SNP) | VAF 49/144 reads (34%) | catalogued as COSV63429635; called by muse, mutect2, varscan2
- KIR2DS4 | c.87T>A p.P29= | Silent (SNP) | VAF 46/128 reads (36%) | called by muse, varscan2
- LAMA2 | c.6168A>G p.T2056= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1386248630, COSV70349624; called by muse, mutect2, varscan2
- LAMA3 | c.6657G>T p.L2219= (on ENST00000313654 / NM_198129.4; = p.L610= on NM_000227.6) | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV52535904; called by muse, mutect2, varscan2
- LCE2D | c.321G>T p.G107= | Silent (SNP) | VAF 23/183 reads (13%) | catalogued as rs562405396, COSV64229045; called by muse, mutect2, varscan2
- LHFPL1 | c.141C>T p.F47= | Silent (SNP) | VAF 15/262 reads (6%) | catalogued as rs949251097, COSV64333567; called by muse, mutect2
- MBNL3 | c.255G>A p.R85= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV63730998; called by muse, mutect2, varscan2
- MRGPRX2 | c.687G>T p.V229= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV61674301; called by muse, mutect2, varscan2
- MUC16 | c.42390C>T p.S14130= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV66692995; called by muse, mutect2, varscan2
- MUC17 | c.13185G>A p.V4395= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV60291185, COSV60300279; called by muse, mutect2, varscan2
- NECTIN4 | c.348C>T p.N116= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs762500186, COSV63512951; called by muse, mutect2, varscan2
- NID1 | c.2424A>C p.P808= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV51621757; called by muse, mutect2
- NIPAL3 | c.243C>T p.F81= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as rs1302877742, COSV99135370; called by muse, mutect2, varscan2
- NIPAL3 | c.244C>T p.L82= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV99135374; called by muse, mutect2, varscan2
- NLRP7 | c.1194C>A p.L398= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV60175805, COSV60184076; called by muse, mutect2, varscan2
- NPC1L1 | c.3063C>T p.N1021= | Silent (SNP) | VAF 73/266 reads (27%) | catalogued as rs746814275, COSV56926052; called by muse, mutect2, varscan2
- NPR3 | c.1239T>C p.Y413= | Silent (SNP) | VAF 69/288 reads (24%) | catalogued as rs368653320; called by muse, mutect2, varscan2
- NTRK3 | c.429G>T p.S143= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs138266478, COSV58125588; called by muse, mutect2, varscan2
- OLIG2 | c.267G>C p.A89= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs562023180, COSV60972716; called by muse, mutect2, varscan2
- OR2A5 | c.633C>G p.L211= | Silent (SNP) | VAF 72/249 reads (29%) | catalogued as COSV68738813, COSV68738914; called by muse, mutect2, varscan2
- OR2L2 | c.678C>G p.R226= | Silent (SNP) | VAF 115/256 reads (45%) | catalogued as COSV63554309; called by muse, mutect2, varscan2
- OR2W3 | c.240G>A p.Q80= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as COSV64457105; called by muse, mutect2, varscan2
- OR51B5 | c.636C>T p.I212= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV56176275; called by muse, mutect2, varscan2
- OR6B1 | c.72G>T p.R24= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV68770245; called by muse, mutect2, varscan2
- OR6C3 | c.342C>A p.A114= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV65571278; called by muse, mutect2, varscan2
- PCNX1 | c.1977A>T p.T659= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as COSV53095812; called by muse, mutect2, varscan2
- PDE6B | c.1263G>A p.L421= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55327161; called by muse, mutect2, varscan2
- PEAR1 | c.474C>A p.P158= | Silent (SNP) | VAF 73/148 reads (49%) | catalogued as COSV52773611; called by muse, mutect2, varscan2
- PIK3R6 | c.1047G>C p.G349= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV61003593; called by muse, mutect2, varscan2
- PMCH | c.132G>A p.L44= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100268285; called by muse, mutect2, varscan2
- PPM1E | c.828G>T p.G276= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV57572244, COSV57575364; called by muse, mutect2, varscan2
- PPP1R18 | c.45C>A p.R15= | Silent (SNP) | VAF 53/267 reads (20%) | catalogued as COSV51296650; called by muse, mutect2, varscan2
- PRKN | c.291G>T p.R97= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV58232365; called by muse, mutect2, varscan2
- PTPN14 | c.597A>G p.A199= | Silent (SNP) | VAF 69/135 reads (51%) | catalogued as COSV65284791; called by muse, mutect2, varscan2
- PWWP2B | c.1608G>T p.T536= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as rs372035621, COSV59449969, COSV59451133; called by muse, mutect2, varscan2
- PYHIN1 | c.1014T>C p.N338= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV63722742; called by muse, mutect2, varscan2
- RAB6C | c.378T>C p.N126= | Silent (SNP) | VAF 80/260 reads (31%) | catalogued as rs779209626, COSV69339537; called by muse, mutect2, varscan2
- RAI2 | c.1419C>A p.S473= | Silent (SNP) | VAF 40/324 reads (12%) | catalogued as COSV58964484, COSV58964693; called by muse, mutect2, varscan2
- RBM19 | c.1221G>T p.R407= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV55689906, COSV55693170; called by muse, mutect2, varscan2
- RNASEH1 | c.468G>T p.P156= | Silent (SNP) | VAF 50/180 reads (28%) | catalogued as COSV59438814; called by muse, mutect2, varscan2
- RPAP1 | c.1114C>T p.L372= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs144541934; called by muse, varscan2
- RYR2 | c.3285A>T p.A1095= | Silent (SNP) | VAF 78/160 reads (49%) | catalogued as COSV63689860; called by muse, mutect2, varscan2
- RYR3 | c.9216C>A p.R3072= (on ENST00000389232; = p.R3073= on NM_001036.6) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1228645063, COSV66793532; called by muse, mutect2, varscan2
- SI | c.3642C>A p.G1214= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52282715; called by muse, mutect2, varscan2
- SLC16A7 | c.579C>G p.S193= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV53892530, COSV53895881; called by muse, mutect2, varscan2
- SLC35A2 | c.162C>T p.I54= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs782174663, COSV55945000; called by muse, mutect2, varscan2
- SLC5A8 | c.399C>T p.V133= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1365888248, COSV73310746; called by muse, mutect2, varscan2
- SLC9C2 | c.204A>T p.G68= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV62946265; called by muse, mutect2, varscan2
- SLITRK2 | c.2532G>A p.Q844= | Silent (SNP) | VAF 73/128 reads (57%) | catalogued as COSV59425997; called by muse, mutect2, varscan2
- SOHLH1 | c.588G>C p.T196= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV53682429; called by muse, mutect2, varscan2
- SYNPO2 | c.3624C>A p.S1208= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV61112083; called by muse, mutect2, varscan2
- SYT7 | c.561G>A p.L187= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV55656381; called by muse, mutect2
- TET3 | c.2628C>T p.I876= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV69643098; called by muse, mutect2, varscan2
- TIGIT | c.282C>T p.T94= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV67328729, COSV67329006; called by muse, mutect2, varscan2
- TLR7 | c.2463G>A p.K821= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs1214091926, COSV66124512; called by muse, mutect2, varscan2
- TNNT3 | c.546C>A p.A182= (on ENST00000397301 / NM_001367846.1; = p.A171= on NM_006757.4) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV53487244; called by muse, mutect2, varscan2
- TRAF5 | c.559T>C p.L187= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV54822930; called by muse, mutect2, varscan2
- TRBC2 | c.237C>A p.R79= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- TRIM27 | c.960G>C p.L320= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV65873633; called by muse, mutect2
- TRPM7 | c.2586A>G p.A862= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV57917324; called by muse, mutect2, varscan2
- UGT1A9 | c.132G>T p.V44= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs747820037, COSV60841599; called by muse, mutect2, varscan2
- UNC5C | c.2160G>A p.Q720= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV71660301; called by muse, mutect2, varscan2
- USH2A | c.2670C>A p.T890= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as rs1164198981, COSV100238639; called by muse, mutect2
- WDHD1 | c.3066C>T p.F1022= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV62214239; called by muse, mutect2, varscan2
- ZBED9 | c.3901C>T p.L1301= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs888063348, COSV71729474; called by muse, mutect2, varscan2
- ZFHX4 | c.6969G>A p.R2323= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV50975187; called by muse, mutect2, varscan2
- ZPBP | c.873A>G p.E291= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs767162535, COSV50426503; called by muse, mutect2, varscan2
- ANKRD13D | c.*466G>T | 3'UTR (SNP) | VAF 23/86 reads (27%) | catalogued as COSV57752459, COSV57752853; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1876G>C | 3'UTR (SNP) | VAF 23/112 reads (21%) | catalogued as COSV57543105; called by muse, mutect2, varscan2
- BEND6 | chr6:56954569 G>T | 5'Flank (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- C7orf66 | n.405G>C | RNA (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- COG5 | c.-62C>A | 5'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as COSV51753416; called by muse, mutect2, varscan2
- DCHS2 | n.3391del | RNA (DEL) | VAF 34/185 reads (18%) | catalogued as COSV100253051; called by mutect2, pindel, varscan2
- EIF4A2 | c.208+128G>T | Intron (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100125573; called by muse, mutect2, varscan2
- MAL | c.*2G>A | 3'UTR (SNP) | VAF 36/133 reads (27%) | catalogued as COSV100015825; called by muse, mutect2, varscan2
- PTPN7 | c.-52-12C>A | Intron (SNP) | VAF 34/71 reads (48%) | catalogued as COSV100459981; called by muse, mutect2, varscan2
- SSPOP | n.6472C>A | RNA (SNP) | VAF 13/91 reads (14%) | catalogued as COSV50487840; called by muse, mutect2, varscan2
- TMEM132E | chr17:34577555 G>T | 5'Flank (SNP) | VAF 10/42 reads (24%) | catalogued as rs549690989; called by muse, mutect2
